Somatic mutation profile of tumor specimen TCGA-2J-AABI-01A (aliquot TCGA-2J-AABI-01A-12D-A40W-08) from TCGA case TCGA-2J-AABI, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 55.6 years (20,316 days).
Specimen TCGA-2J-AABI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0aa4babc-0373-4771-a07f-9083685d04db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AABI-10A (Blood Derived Normal), aliquot TCGA-2J-AABI-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78fffa10-5888-4985-95c4-64fd2727fcda

The open-access MAF lists 39 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Frame Shift Del 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 294/496 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGAP1 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs773218170, COSV58319853, COSV58340917; called by muse, mutect2, varscan2
- APCDD1 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 229/655 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752102915, COSV99051293; called by muse, mutect2, varscan2
- CACNA1B | c.6551G>A p.R2184H | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756380021, COSV99496276; called by muse, varscan2
- CDKN2A | c.47_50del p.L16Pfs*9 | Frame Shift Del (DEL) | VAF 66/122 reads (54%) | catalogued as rs587782206; called by pindel, varscan2
- CHD9 | c.2388C>G p.Y796* | Nonsense Mutation (SNP) | VAF 32/105 reads (30%) | catalogued as COSV99528943; called by muse, mutect2, varscan2
- KCNA6 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 183/1062 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768498; called by muse, mutect2, varscan2
- KCNN2 | c.582+2T>C p.X194_splice (on ENST00000264773; = p.X406_splice on NM_021614.4) | Splice Site (SNP) | VAF 147/367 reads (40%) | catalogued as COSV99299314; called by muse, mutect2, varscan2
- LRP4 | c.4516C>T p.R1506W | Missense Mutation (SNP) | VAF 131/390 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766025454, COSV66135911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCF2 | c.743C>G p.T248R | Missense Mutation (SNP) | VAF 101/366 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs750930370, COSV100644640; called by muse, mutect2, varscan2
- MPV17L2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 98/176 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99717931; called by muse, mutect2, varscan2
- MYO18B | c.7073G>T p.R2358I | Missense Mutation (SNP) | VAF 185/366 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as COSV100123106; called by muse, mutect2, varscan2
- NOX1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399692470, COSV54195846; called by muse, mutect2, varscan2
- NPTX1 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as COSV100150944; called by muse, mutect2, varscan2
- OR11L1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100869453, COSV63315963; called by muse, mutect2, varscan2
- PCDHA6 | c.2198C>T p.T733M | Missense Mutation (SNP) | VAF 113/325 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); catalogued as rs1554132712, COSV65344590; called by muse, mutect2, varscan2
- PSMD1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 38/710 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV100433466; called by muse, mutect2
- SCN4A | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 94/236 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220797445, COSV101438395; called by muse, mutect2, varscan2
- SI | c.4963C>T p.R1655W | Missense Mutation (SNP) | VAF 321/994 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs760505676, COSV52268101; called by muse, mutect2, varscan2
- SIAH2 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 181/465 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100469178; called by muse, mutect2, varscan2
- TACR3 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 293/923 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs553885967, COSV59197525; called by muse, mutect2, varscan2
- TTC21A | c.2773G>A p.V925M | Missense Mutation (SNP) | VAF 444/867 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100087165; called by muse, mutect2, varscan2
- VPS13C | c.5483A>G p.N1828S (on ENST00000644861 / NM_020821.3; = p.N1785S on NM_017684.5) | Missense Mutation (SNP) | VAF 102/338 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99827865; called by muse, mutect2, varscan2
- WDR17 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 167/488 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV99707257; called by muse, mutect2, varscan2
- ZMYND12 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763895321, COSV100999791; called by muse, mutect2, varscan2
- ZNF106 | c.2056C>T p.H686Y | Missense Mutation (SNP) | VAF 256/748 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV99782385; called by muse, mutect2, varscan2
- ZNF283 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 190/354 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV61031001; called by muse, mutect2, varscan2
- ABL1 | c.41G>T p.R14M | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SMAD4 | c.809del p.G270Efs*66 | Frame Shift Del (DEL) | VAF 185/435 reads (43%) | called by mutect2, pindel, varscan2
- TP53 | c.648_649dup p.V217Gfs*31 | Frame Shift Ins (INS) | VAF 60/151 reads (40%) | called by mutect2, pindel, varscan2
- COL1A2 | c.1233T>C p.D411= | Silent (SNP) | VAF 162/495 reads (33%) | catalogued as rs1164504050, COSV99799176; called by muse, mutect2, varscan2
- ELOA3B | c.846C>T p.Y282= | Silent (SNP) | VAF 60/1834 reads (3%) | catalogued as rs1322096949; called by muse, mutect2
- IGDCC3 | c.162C>T p.V54= | Silent (SNP) | VAF 62/153 reads (41%) | catalogued as COSV100030950; called by muse, mutect2, varscan2
- MAGEA12 | c.456C>T p.S152= | Silent (SNP) | VAF 374/1052 reads (36%) | catalogued as COSV100756860; called by muse, mutect2, varscan2
- MYLK | c.3750C>T p.R1250= | Silent (SNP) | VAF 98/275 reads (36%) | catalogued as rs201873975, COSV60619981; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEO1 | c.1374G>A p.T458= | Silent (SNP) | VAF 217/542 reads (40%) | catalogued as rs763026515, COSV56078779; called by muse, mutect2, varscan2
- PCDHA12 | c.2196C>T p.C732= | Silent (SNP) | VAF 76/212 reads (36%) | catalogued as COSV99165495; called by muse, mutect2, varscan2
- PPP1R3D | c.756C>T p.R252= | Silent (SNP) | VAF 81/237 reads (34%) | catalogued as rs766731315, COSV100674469; called by muse, mutect2, varscan2
- SLC8A3 | c.2037G>A p.T679= (on ENST00000381269 / NM_183002.3; = p.T677= on NM_033262.4) | Silent (SNP) | VAF 98/186 reads (53%) | catalogued as rs781373778, COSV53692012, COSV99385974; called by muse, mutect2, varscan2
